Somatic mutation profile of tumor specimen 0DDRN8 from CCDI case PBBNSW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.9 years (6,161 days).
Specimen 0DDRN8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd912b79-5b09-47b1-9f57-e15b2cd3ba0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDRN9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4357ea9b-48de-4d63-90a5-cee7f519e56e

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5, Missense Mutation 5, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 271/680 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KLF11 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 20/695 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1212837797; called by muse, mutect2
- MC4R | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 139/432 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.251); catalogued as rs758068983; called by muse, mutect2, varscan2
- BCORL1 | c.4472+1_4472+2del p.X1491_splice | Splice Site (DEL) | VAF 97/137 reads (71%) | called by mutect2, varscan2
- CDK15 | c.134T>G p.L45R | Missense Mutation (SNP) | VAF 135/602 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- COBLL1 | c.875C>T p.T292I (on ENST00000392717; = p.T254I on NM_014900.5) | Missense Mutation (SNP) | VAF 118/381 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLXNB3 | c.906G>T p.V302= | Silent (SNP) | VAF 183/258 reads (71%) | called by muse, mutect2, varscan2
- PPP4R2 | c.1104C>T p.G368= | Silent (SNP) | VAF 321/447 reads (72%) | catalogued as rs1328570000; called by muse, mutect2, varscan2
- ATR | c.7193-94A>G | Intron (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- GPATCH2 | c.1277+45dup | Intron (INS) | VAF 64/189 reads (34%) | catalogued as rs746356596; called by mutect2, varscan2
- PIGB | c.1124-83C>G | Intron (SNP) | VAF 24/80 reads (30%) | called by muse, varscan2
- POTEG | c.1055+31G>T | Intron (SNP) | VAF 48/356 reads (13%) | called by muse, mutect2, varscan2
- TWF2 | c.761-61C>G | Intron (SNP) | VAF 105/299 reads (35%) | called by muse, mutect2, varscan2
